MMRF case MMRF_1588 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/79596d6d-0e0f-4955-9035-5008105deb45

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 67 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 67.5 years (24,657 days); ISS stage: I; Days to last known disease status: 1,157 days (3.2 years); Days to last follow up: 1,157 days (3.2 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 161 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 205 days; Days to treatment end: 205 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 205 days; Days to treatment end: 205 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -76 (ECOG 1): M Protein 3.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 12.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.44 mg/dL; Immunoglobulin G 48.3 g/L; Immunoglobulin A 0.45 g/L; Immunoglobulin M 0.28 g/L; Beta 2 Microglobulin 2.6 µg/mL; Lactate Dehydrogenase 3 µkat/L; Hemoglobin 9.05 mmol/L; Leukocytes 34.6 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 232 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 10.5 g/dL; Glucose 4.84 mmol/L; C-Reactive Protein 1.4 mg/dL.
- Day 1 (ECOG 0): Immunoglobulin G 46.4 g/L; Immunoglobulin A 0.29 g/L; Immunoglobulin M 0.29 g/L; Hemoglobin 8.31 mmol/L; Leukocytes 33.7 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 205 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.1 mmol/L; Albumin 34 g/L; Total Protein 9.2 g/dL; Glucose 7.48 mmol/L.
- Day 112: M Protein 0.4 g/dL; Immunoglobulin G 10.1 g/L; Immunoglobulin A 0.46 g/L; Immunoglobulin M 0.16 g/L; Hemoglobin 7.94 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 189 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.25 mmol/L; Albumin 36 g/L; Total Protein 7 g/dL; Glucose 11.7 mmol/L.
- Day 205 (ECOG 0): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.883 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.668 mg/dL; Immunoglobulin G 9.8 g/L; Immunoglobulin A 0.44 g/L; Immunoglobulin M 0.08 g/L; Hemoglobin 8.18 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.18 mmol/L; Albumin 35 g/L; Total Protein 6.9 g/dL; Glucose 8.36 mmol/L.
- Day 288 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.47 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.955 mg/dL; Immunoglobulin G 12.2 g/L; Immunoglobulin A 0.34 g/L; Immunoglobulin M 0.17 g/L; Beta 2 Microglobulin 2.89 µg/mL; Lactate Dehydrogenase 3.67 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 160 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.2 mmol/L; Albumin 37 g/L; Total Protein 7.2 g/dL; Glucose 3.08 mmol/L.
- Day 477 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.47 mg/dL; Immunoglobulin G 11 g/L; Immunoglobulin A 0.52 g/L; Immunoglobulin M 0.55 g/L; Beta 2 Microglobulin 2.94 µg/mL; Lactate Dehydrogenase 4.95 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 148 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.23 mmol/L; Albumin 39 g/L; Total Protein 7.3 g/dL; Glucose 5.12 mmol/L.
- Day 567 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.33 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.9 mg/dL; Hemoglobin 8.06 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 149 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.15 mmol/L; Albumin 38 g/L; Total Protein 6.9 g/dL; Glucose 4.51 mmol/L.
- Day 647 (ECOG 0): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.25 mg/dL; Hemoglobin 9.49 mmol/L; Leukocytes 11.1 ×10⁹/L; Absolute Neutrophil 8.4 ×10⁹/L; Platelets 183 ×10⁹/L; Creatinine 109 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.48 mmol/L; Albumin 47 g/L; Total Protein 7.2 g/dL; Glucose 6.71 mmol/L.
- Day 721 (ECOG 0): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.93 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.6 mg/dL; Hemoglobin 8.93 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 159 ×10⁹/L; Creatinine 107 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 7.2 g/dL; Glucose 5.28 mmol/L.
- Day 812 (ECOG 0): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.38 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.56 mg/dL; Immunoglobulin G 11 g/L; Immunoglobulin A 0.52 g/L; Immunoglobulin M 0.55 g/L; Beta 2 Microglobulin 2.94 µg/mL; Hemoglobin 8.74 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 109 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.2 mmol/L; Albumin 39 g/L; Total Protein 7.3 g/dL; Glucose 3.8 mmol/L.
- Day 931: M Protein 0.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.34 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.95 mg/dL; Immunoglobulin G 14.5 g/L; Immunoglobulin A 1.09 g/L; Immunoglobulin M 0.69 g/L; Beta 2 Microglobulin 2.81 µg/mL; Hemoglobin 9.05 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 7.5 g/dL; Glucose 5.83 mmol/L.
- Day 1,067 (ECOG 0): M Protein 1.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.13 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.02 mg/dL; Immunoglobulin G 15.4 g/L; Immunoglobulin A 1.14 g/L; Immunoglobulin M 0.7 g/L; Beta 2 Microglobulin 3.03 µg/mL; Hemoglobin 9.05 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 165 ×10⁹/L; Creatinine 99.9 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.13 mmol/L; Albumin 38 g/L; Total Protein 7.5 g/dL; Glucose 6.05 mmol/L.
- Day 1,157 (ECOG 0): M Protein 1.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.84 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.8 mg/dL; Immunoglobulin G 18.6 g/L; Immunoglobulin A 1.43 g/L; Immunoglobulin M 0.89 g/L; Beta 2 Microglobulin 3.33 µg/mL; Hemoglobin 8.25 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 181 ×10⁹/L; Creatinine 109 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.18 mmol/L; Albumin 36 g/L; Total Protein 7.7 g/dL; Glucose 2.97 mmol/L.

Other clinical attributes
- Day -76: Weight: 102 kg; Height: 187 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Breast Cancer.

Biospecimens (2 samples)
- Sample MMRF_1588_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -76 days.
- Sample MMRF_1588_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -76 days.
